Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A8XH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A8XH-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

DOB:

Accession:

MRN:

PAN:

Surgical Pathology Report

Final

ICD O3
Carcinoma squamous cell
NOS 8070/3
Site Cervix NOS C53.9
11/17/14

SURGICAL PATHOLOGY REPORT
* Consult Report *
FINAL

Patient Name:

Address:

Gender: F

DOB:

(Age:

Physician(s):

M.D.

Service:

Location:

MRN:

Hospital #:

Patient Type:

Accession

Taken:

Received:

Accessioned:

Reported:

Other Related Clinical Data:

DIAGNOSIS

UTERUS, ENDOCERVIX, BIOPSY

- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED
- NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED

UTERUS, CERVIX, 12 O'CLOCK, BIOPSY

- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED
- NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED

By this signature, I attest that the above diagnosis is
based upon my personal
examination of the slides (and/or other material indicated in the
diagnosis)

Ph.D.

***Report Electronically Reviewed and Signed Out By M.D.,

Ph.D.***

Microscopic Description and Comment

Microscopic examination substantiates the above cited diagnosis.

M.D.

History

The patient is a year old woman.

Material(s) Received

Received two slides labeled with accompanying corresponding pathology
report. The material originates from
The performance characteristics of some immunohistochemical stains, fluorescence
in-situ hybridization tests and immunophenotyping by flow cytometry cited in
this report (if any) were determined by the
as part of an ongoing quality assurance program and in
compliance with federally mandated regulations drawn from the Clinical
Laboratory Improvement Act of 1988 (CLIA '88). Some of these tests rely on the
use of "analyte specific reagents" and are subject to specific labeling
requirements by the US Food and Drug Administration. Such diagnostic tests may

[page 2 of 2]
Patient Name: [REDACTED]

DOB: [REDACTED]

Accession: [REDACTED]

MRN: [REDACTED]

PAN: [REDACTED]

only be performed in a facility that is certified by the Department of Health and Human Services as a high complexity laboratory under CLIA '88. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to the report:

This test was developed and its performance characteristics determined by the [REDACTED]. It has not been cleared or approved by the U. S. Food and Drug Administration.

Source: NCI Genomic Data Commons file 6d76b31e-41c0-41d0-9be7-d95564a3935a (TCGA-C5-A8XH.3902118B-D919-41B7-99D1-0D5140967526.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).